Somatic mutation profile of tumor specimen HCM-BROD-0194-C15-86A (aliquot HCM-BROD-0194-C15-86A-01D-A937-36) from HCMI case HCM-BROD-0194-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 47.8 years (17,477 days).
Specimen HCM-BROD-0194-C15-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8be35ce5-278c-4d32-bae3-1953f1cd7738.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0194-C15-10B (Blood Derived Normal), aliquot HCM-BROD-0194-C15-10B-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33e436a8-00dd-496d-ad7f-65969aaa4a98

The open-access MAF lists 150 somatic variants for this specimen: 97 protein-altering or splice-affecting, 43 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 43, Nonsense Mutation 4, Intron 3, 3'UTR 3, Frame Shift Ins 2, 5'UTR 2, Frame Shift Del 2, Splice Region 1, Splice Site 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.44G>A p.W15* | Nonsense Mutation (SNP) | VAF 599/602 reads (100%) | catalogued as rs876658556, CM960269, COSV58683138, COSV58721704; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.398T>A p.M133K | Missense Mutation (SNP) | VAF 348/348 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.061); catalogued as CM910373, CM973400, COSV52744834, COSV52795528, COSV52821486, COSV52852024; called by muse, mutect2, varscan2
- ADAMTS12 | c.1391A>C p.K464T | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs780506138, COSV61255039, COSV61262098; called by muse, mutect2
- ALDH1A2 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 68/376 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs778997757, COSV51092676; called by muse, mutect2, varscan2
- AVPR1A | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 260/446 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767540299; called by muse, varscan2
- BAHCC1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 123/351 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782753355; called by muse, mutect2, varscan2
- BEND4 | c.264dup p.G89Rfs*65 | Frame Shift Ins (INS) | VAF 24/172 reads (14%) | catalogued as rs1246615541; called by mutect2, varscan2
- BRIP1 | c.512G>T p.R171I | Missense Mutation (SNP) | VAF 84/234 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99370435; called by muse, mutect2, varscan2
- CHIA | c.1152G>T p.K384N (on ENST00000343320; = p.K276N on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/422 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.223); catalogued as COSV58477792; called by muse, mutect2
- CLASP2 | c.1246C>T p.L416F | Missense Mutation (SNP) | VAF 262/308 reads (85%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as rs963434755; called by muse, mutect2, varscan2
- CSF2RB | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 52/534 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as rs753738312; called by muse, mutect2
- CYLC1 | c.251T>G p.I84S | Missense Mutation (SNP) | VAF 16/368 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs1358418612, COSV61415383; called by muse, mutect2
- DPP6 | c.266C>T p.P89L (on ENST00000377770 / NM_001364500.2; = p.P27L on NM_001936.5) | Missense Mutation (SNP) | VAF 252/278 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs567844586; called by muse, mutect2, varscan2
- DRAXIN | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 45/722 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as rs1001837034; called by muse, mutect2
- EFS | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 133/343 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs780112461, COSV53731809; called by muse, mutect2, varscan2
- EPHA5 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 152/175 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs772693559, COSV56639156; called by muse, mutect2, varscan2
- EPHB2 | c.1958A>G p.K653R (on ENST00000400191 / NM_001309193.2; = p.K654R on NM_004442.7) | Missense Mutation (SNP) | VAF 99/398 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1007510252; called by muse, mutect2, varscan2
- ERBB3 | c.2036G>T p.R679L | Missense Mutation (SNP) | VAF 283/440 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57252242; called by muse, mutect2, varscan2
- ERC2 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 289/328 reads (88%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as rs866429245, COSV55642982; called by muse, mutect2, varscan2
- FBN1 | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 24/392 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370575495; ClinVar: uncertain significance; called by muse, mutect2
- GPR6 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 168/551 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs898785367, COSV51571702, COSV99254150; called by muse, varscan2
- ITPR3 | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 161/603 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369403597; called by muse, mutect2, varscan2
- KCTD8 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 275/330 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs549391615, COSV63588118; called by muse, mutect2, varscan2
- KIF19 | c.1772G>A p.R591H | Missense Mutation (SNP) | VAF 18/650 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs1348486661; called by muse, mutect2
- KLHL42 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 204/3328 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs759832133; called by muse, mutect2
- MYOC | c.729C>T p.T243= | Splice Region (SNP) | VAF 40/247 reads (16%) | catalogued as rs1014944863, COSV50675092, COSV50679823; called by muse, mutect2, varscan2
- NDST3 | c.904G>C p.D302H | Missense Mutation (SNP) | VAF 53/288 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56627470; called by muse, mutect2, varscan2
- PNPLA7 | c.3169G>A p.V1057M | Missense Mutation (SNP) | VAF 120/261 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141633875; called by muse, mutect2, varscan2
- PRDM11 | c.1349G>A p.R450H (on ENST00000530656 / NM_001359633.1; = p.R416H on NM_001256695.1) | Missense Mutation (SNP) | VAF 43/382 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs755641215; called by muse, mutect2, varscan2
- PRR14L | c.100A>G p.R34G | Missense Mutation (SNP) | VAF 119/425 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1332006583; called by muse, mutect2, varscan2
- RAB9B | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 267/267 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.241); catalogued as rs1321964920, COSV54588235; called by muse, mutect2, varscan2
- RPAP1 | c.2846G>A p.R949H | Missense Mutation (SNP) | VAF 135/392 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.066); catalogued as rs764481480; called by muse, mutect2, varscan2
- SLC4A4 | c.2242G>A p.V748M (on ENST00000264485 / NM_001098484.3; = p.V704M on NM_003759.4) | Missense Mutation (SNP) | VAF 117/305 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs760895286, COSV52614711; called by muse, mutect2, varscan2
- SORCS3 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 167/275 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs142652556; called by muse, mutect2, varscan2
- SYNE1 | c.5783G>A p.G1928D (on ENST00000367255 / NM_182961.4; = p.G1935D on NM_033071.3) | Missense Mutation (SNP) | VAF 288/595 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as rs1241708653, COSV99569895; called by muse, varscan2
- TECTA | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs886047837, COSV50690989; ClinVar: uncertain significance; called by muse, mutect2
- TMEM132C | c.2929G>A p.E977K | Missense Mutation (SNP) | VAF 14/408 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as COSV59417811; called by muse, mutect2
- TYR | c.368T>C p.I123T | Missense Mutation (SNP) | VAF 39/311 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM083853; called by muse, mutect2, varscan2
- VN1R4 | c.656G>T p.S219I | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV60805050; called by muse, mutect2
- WDR27 | c.1412A>G p.N471S | Missense Mutation (SNP) | VAF 184/411 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs752264499; called by muse, mutect2, varscan2
- ZNF302 | c.734_735del p.R245Nfs*11 (on ENST00000627982; = p.R166Nfs*11 on NM_018443.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 102/304 reads (34%) | catalogued as rs763548605; called by pindel, varscan2
- ZNF609 | c.2435G>A p.R812H | Missense Mutation (SNP) | VAF 73/547 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs182000412; called by muse, mutect2, varscan2
- APBB2 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 279/340 reads (82%) | SIFT tolerated (0.21); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- ARAP2 | c.5022G>T p.K1674N | Missense Mutation (SNP) | VAF 202/244 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- ASH1L | c.6807dup p.Q2270Tfs*5 (on ENST00000368346 / NM_001366177.2; = p.Q2265Tfs*5 on NM_018489.3) | Frame Shift Ins (INS) | VAF 338/610 reads (55%) | called by mutect2, pindel, varscan2
- BAZ2B | c.1531A>G p.T511A | Missense Mutation (SNP) | VAF 16/448 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- C5 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 112/278 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CGRRF1 | c.892T>G p.C298G | Missense Mutation (SNP) | VAF 164/457 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD6 | c.2334G>A p.M778I | Missense Mutation (SNP) | VAF 31/659 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); called by muse, mutect2
- CNTLN | c.2477C>G p.T826S | Missense Mutation (SNP) | VAF 82/478 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- CNTN5 | c.601A>C p.T201P | Missense Mutation (SNP) | VAF 258/259 reads (100%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.725); called by muse, varscan2
- COL24A1 | c.2143G>A p.D715N | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- DYRK1A | c.2011T>C p.S671P | Missense Mutation (SNP) | VAF 371/372 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ELAPOR2 | c.925G>A p.V309M (on ENST00000450689 / NM_001142749.3; = p.V142M on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 177/311 reads (57%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- EMILIN1 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 40/696 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.169); called by muse, mutect2
- EPHA8 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.134); called by muse, mutect2
- F2RL3 | c.530C>G p.A177G | Missense Mutation (SNP) | VAF 73/496 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- FBXO43 | c.1102G>C p.V368L | Missense Mutation (SNP) | VAF 94/410 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- GK2 | c.231A>C p.E77D | Missense Mutation (SNP) | VAF 15/343 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.012); called by muse, mutect2
- HECTD2 | c.1669C>T p.Q557* | Nonsense Mutation (SNP) | VAF 17/322 reads (5%) | called by muse, mutect2
- HIF1A | c.194G>C p.S65T | Missense Mutation (SNP) | VAF 79/325 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- HIVEP1 | c.5834G>A p.C1945Y | Missense Mutation (SNP) | VAF 241/397 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOOK2 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 220/258 reads (85%) | called by muse, varscan2
- IGHV6-1 | c.299A>T p.N100I | Missense Mutation (SNP) | VAF 232/373 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1D-16 | c.200A>C p.K67T | Missense Mutation (SNP) | VAF 33/506 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.168); called by muse, mutect2
- KCNS1 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 56/566 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- KDM2B | c.3420G>C p.Q1140H | Missense Mutation (SNP) | VAF 17/322 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- KIF5C | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 102/320 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- LRRC1 | c.504-1G>C p.X168_splice | Splice Site (SNP) | VAF 59/238 reads (25%) | called by muse, varscan2
- MAG | c.626A>T p.E209V | Missense Mutation (SNP) | VAF 70/611 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- MAGEB16 | c.755A>C p.K252T | Missense Mutation (SNP) | VAF 253/253 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.439); called by mutect2, varscan2
- NANS | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 83/354 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NHSL1 | c.910A>G p.N304D | Missense Mutation (SNP) | VAF 133/684 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- OR10K2 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 182/208 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PDCD2L | c.695A>G p.N232S | Missense Mutation (SNP) | VAF 133/263 reads (51%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN21 | c.2101C>G p.L701V | Missense Mutation (SNP) | VAF 241/521 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SGCZ | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 228/1127 reads (20%) | called by muse, mutect2, varscan2
- SGCZ | c.30G>T p.E10D | Missense Mutation (SNP) | VAF 226/1130 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLCO4A1 | c.686T>A p.V229D | Missense Mutation (SNP) | VAF 124/942 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by mutect2, varscan2
- SMAP1 | c.445T>G p.L149V | Missense Mutation (SNP) | VAF 94/328 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- STARD9 | c.5845T>A p.S1949T | Missense Mutation (SNP) | VAF 146/429 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- SYNE1 | c.8921C>T p.A2974V (on ENST00000367255 / NM_182961.4; = p.A2981V on NM_033071.3) | Missense Mutation (SNP) | VAF 249/481 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TARS2 | c.1603T>A p.F535I | Missense Mutation (SNP) | VAF 593/811 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TCERG1L | c.181G>T p.V61L | Missense Mutation (SNP) | VAF 92/295 reads (31%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX13C | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 53/270 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TGFB3 | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 22/454 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); called by muse, mutect2
- TMEM121B | c.37T>C p.S13P | Missense Mutation (SNP) | VAF 133/466 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNC | c.3855G>C p.Q1285H | Missense Mutation (SNP) | VAF 17/502 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2
- TPTE | c.1656A>C p.*552Yext*2 (on ENST00000618007 / NM_199261.4; = p.*534Yext*2 on NM_199259.4) | Nonstop Mutation (SNP) | VAF 22/378 reads (6%) | called by muse, mutect2
- TRHDE | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 396/973 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPM5 | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2
- USP5 | c.1753A>C p.K585Q | Missense Mutation (SNP) | VAF 206/308 reads (67%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- VEGFC | c.507G>C p.E169D | Missense Mutation (SNP) | VAF 162/274 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- WNK2 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 133/252 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF527 | c.1453C>T p.L485F | Missense Mutation (SNP) | VAF 242/463 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- ZNF675 | c.1669del p.I557Yfs*35 | Frame Shift Del (DEL) | VAF 109/452 reads (24%) | called by mutect2, pindel, varscan2
- ZNF721 | c.600G>T p.K200N (on ENST00000338977; = p.K212N on NM_133474.4) | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2
- ABCA1 | c.4722C>G p.L1574= | Silent (SNP) | VAF 188/346 reads (54%) | called by muse, mutect2
- APCS | c.453C>A p.V151= | Silent (SNP) | VAF 128/505 reads (25%) | called by muse, mutect2, varscan2
- BASP1 | c.135C>T p.A45= | Silent (SNP) | VAF 89/548 reads (16%) | called by muse, mutect2, varscan2
- CASKIN1 | c.3168C>T p.G1056= | Silent (SNP) | VAF 204/481 reads (42%) | catalogued as rs774444876; called by muse, mutect2, varscan2
- CDH15 | c.1392C>T p.T464= | Silent (SNP) | VAF 42/584 reads (7%) | catalogued as rs768449943; called by muse, mutect2
- CNP | c.525G>A p.K175= | Silent (SNP) | VAF 50/614 reads (8%) | called by muse, mutect2
- CNTNAP5 | c.516C>T p.Y172= | Silent (SNP) | VAF 92/306 reads (30%) | catalogued as rs368252422, COSV70484949; called by muse, mutect2, varscan2
- CPEB1 | c.64C>T p.L22= | Silent (SNP) | VAF 121/358 reads (34%) | called by muse, mutect2, varscan2
- CYLC1 | c.624G>A p.K208= | Silent (SNP) | VAF 29/236 reads (12%) | catalogued as rs1442443985; called by muse, mutect2, varscan2
- CYP4F2 | c.810C>A p.V270= | Silent (SNP) | VAF 50/405 reads (12%) | called by muse, mutect2, varscan2
- DENND3 | c.3351C>T p.L1117= | Silent (SNP) | VAF 92/531 reads (17%) | catalogued as rs373954188; called by muse, varscan2
- EDEM3 | c.2370T>C p.S790= | Silent (SNP) | VAF 119/329 reads (36%) | called by muse, mutect2, varscan2
- EME1 | c.1263C>G p.A421= | Silent (SNP) | VAF 35/387 reads (9%) | catalogued as rs367778832; called by muse, mutect2
- FCGR3B | c.129G>T p.V43= | Silent (SNP) | VAF 250/254 reads (98%) | called by muse, mutect2
- FGF23 | c.549C>T p.D183= | Silent (SNP) | VAF 183/570 reads (32%) | catalogued as rs369808475; called by muse, mutect2, varscan2
- FYCO1 | c.4149G>A p.E1383= | Silent (SNP) | VAF 337/385 reads (88%) | called by muse, mutect2, varscan2
- GABRR2 | c.1293T>A p.G431= | Silent (SNP) | VAF 22/526 reads (4%) | called by muse, mutect2
- GPR180 | c.9G>A p.G3= | Silent (SNP) | VAF 196/208 reads (94%) | catalogued as rs961691083; called by muse, mutect2, varscan2
- GSDMD | c.868C>T p.L290= | Silent (SNP) | VAF 130/745 reads (17%) | called by muse, mutect2, varscan2
- HOMER2 | c.66G>A p.K22= | Silent (SNP) | VAF 161/458 reads (35%) | catalogued as rs771821197; called by muse, mutect2, varscan2
- IGLV1-40 | c.225G>T p.R75= | Silent (SNP) | VAF 303/467 reads (65%) | called by muse, mutect2, varscan2
- ITIH5 | c.591C>T p.I197= | Silent (SNP) | VAF 119/350 reads (34%) | catalogued as rs369114884, COSV56904119, COSV56912641; called by muse, mutect2, varscan2
- KIF2B | c.93C>T p.Y31= | Silent (SNP) | VAF 104/366 reads (28%) | catalogued as rs775762338; called by muse, mutect2, varscan2
- KRTDAP | c.201C>T p.H67= | Silent (SNP) | VAF 238/441 reads (54%) | catalogued as rs766841840; called by muse, mutect2, varscan2
- MEX3B | c.510C>T p.R170= | Silent (SNP) | VAF 86/602 reads (14%) | catalogued as rs1328785948; called by muse, mutect2, varscan2
- MOB3C | c.639G>C p.R213= | Silent (SNP) | VAF 210/344 reads (61%) | catalogued as rs1295333067; called by muse, mutect2, varscan2
- MTCH1 | c.165G>A p.R55= | Silent (SNP) | VAF 245/663 reads (37%) | called by muse, mutect2, varscan2
- NCOR2 | c.7524G>A p.E2508= | Silent (SNP) | VAF 207/207 reads (100%) | called by muse, mutect2, varscan2
- NLRP8 | c.939T>G p.S313= | Silent (SNP) | VAF 20/654 reads (3%) | called by muse, mutect2
- NR5A1 | c.606C>T p.A202= | Silent (SNP) | VAF 259/668 reads (39%) | called by muse, mutect2, varscan2
- NRIP1 | c.264G>A p.Q88= | Silent (SNP) | VAF 22/356 reads (6%) | catalogued as rs761171250; called by muse, mutect2
- OXCT1 | c.486G>A p.G162= | Silent (SNP) | VAF 227/350 reads (65%) | called by muse, mutect2, varscan2
- PBXIP1 | c.1023G>T p.L341= | Silent (SNP) | VAF 300/1744 reads (17%) | called by muse, mutect2, varscan2
- PGR | c.1086G>A p.A362= | Silent (SNP) | VAF 278/286 reads (97%) | catalogued as rs142077957; called by muse, varscan2
- PRLHR | c.12G>A p.S4= | Silent (SNP) | VAF 126/250 reads (50%) | catalogued as rs867151973, COSV53304059; called by muse, mutect2, varscan2
- PXDNL | c.2295C>T p.R765= | Silent (SNP) | VAF 308/580 reads (53%) | catalogued as COSV100681376; called by muse, varscan2
- RAD51AP2 | c.783G>A p.Q261= | Silent (SNP) | VAF 60/340 reads (18%) | called by muse, mutect2, varscan2
- REELD1 | c.735T>G p.T245= | Silent (SNP) | VAF 199/295 reads (67%) | called by muse, mutect2, varscan2
- RSPH10B | c.1599C>T p.F533= | Silent (SNP) | VAF 48/128 reads (38%) | catalogued as rs771388883, COSV100521199; called by mutect2, varscan2
- RSPH10B2 | c.1599C>T p.C533= | Silent (SNP) | VAF 60/307 reads (20%) | catalogued as rs748374279; called by muse, mutect2, varscan2
- STYXL2 | c.3018G>C p.R1006= | Silent (SNP) | VAF 30/501 reads (6%) | called by muse, mutect2
- USH2A | c.7017A>G p.T2339= | Silent (SNP) | VAF 199/354 reads (56%) | catalogued as rs1426861450, COSV100233083; called by muse, mutect2, varscan2
- VPS13B | c.10275G>A p.P3425= | Silent (SNP) | VAF 40/519 reads (8%) | catalogued as rs151315104; called by muse, mutect2
- ADAM7 | c.579+17T>C | Intron (SNP) | VAF 16/242 reads (7%) | called by muse, mutect2
- BIRC7 | c.450-99C>T | Intron (SNP) | VAF 142/1107 reads (13%) | catalogued as rs530112822; called by muse, mutect2, varscan2
- C2CD4A | c.*1779A>C | 3'UTR (SNP) | VAF 19/224 reads (8%) | called by muse, mutect2
- CHEK1 | chr11:125625879 G>A | 5'Flank (SNP) | VAF 184/436 reads (42%) | catalogued as rs946157626; called by muse, mutect2, varscan2
- FAM21FP | n.179C>G | RNA (SNP) | VAF 246/482 reads (51%) | called by muse, mutect2, varscan2
- NMNAT2 | c.86-10900G>A | Intron (SNP) | VAF 32/368 reads (9%) | called by muse, mutect2
- PITPNB | c.*53T>A | 3'UTR (SNP) | VAF 125/367 reads (34%) | called by muse, mutect2, varscan2
- PRR30 | c.*3C>T | 3'UTR (SNP) | VAF 212/662 reads (32%) | catalogued as COSV99574229; called by muse, mutect2
- RNF213 | c.-1C>A | 5'UTR (SNP) | VAF 163/251 reads (65%) | called by muse, mutect2, varscan2
- VPS11 | c.-520G>C | 5'UTR (SNP) | VAF 17/417 reads (4%) | catalogued as rs1425754248; called by muse, mutect2
